Somatic mutation profile of tumor specimen TARGET-10-PAPEJA-09A (aliquot TARGET-10-PAPEJA-09A-01D) from TARGET case TARGET-10-PAPEJA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,221 days).
Specimen TARGET-10-PAPEJA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef6b0e95-48d7-4150-a716-6e2708f6e534.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEJA-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEJA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be427d0d-f283-4d7e-95a4-012deed04bfd

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Splice Region 1, Nonsense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPG2 | c.5657G>A p.R1886H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as rs370745167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUCKS1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs764048321, COSV65652695; called by muse, mutect2, varscan2
- SBK2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV60015521; called by muse, mutect2, varscan2
- TGM4 | c.972-6C>T | Splice Region (SNP) | VAF 4/72 reads (6%) | catalogued as rs200355345; called by muse, mutect2
- ZFHX4 | c.7976G>A p.R2659Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51474147, COSV99270158; called by muse, mutect2, varscan2
- A1CF | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYBG3 | c.3904G>T p.E1302* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- DLG3 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162675 ACACTCACACAGTGATAC>CCA | Missense Mutation (DEL) | VAF 15/48 reads (31%) | called by pindel, varscan2*
- LMAN1 | c.344G>C p.R115T | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2
- KIR2DL1 | c.243C>A p.S81= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV99382799; called by muse, mutect2, varscan2
- PCDH18 | c.*119G>T | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, varscan2
